Somatic mutation profile of tumor specimen TCGA-BD-A2L6-01A (aliquot TCGA-BD-A2L6-01A-11D-A20W-10) from TCGA case TCGA-BD-A2L6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 69.8 years (25,489 days).
Specimen TCGA-BD-A2L6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 563d0d7e-8c89-4cb0-8661-ef8d38cd43b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BD-A2L6-11A (Solid Tissue Normal), aliquot TCGA-BD-A2L6-11A-21D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47e2f2e4-36ed-4580-8cce-62876a79f242

The open-access MAF lists 85 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Frame Shift Ins 5, Nonsense Mutation 5, Frame Shift Del 2, Intron 1, 3'UTR 1, 5'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 96/182 reads (53%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCC8 | c.4090G>T p.V1364F | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs138642224, COSV100217572, COSV100217706; called by muse, mutect2, varscan2
- ADAMTS1 | c.2028+1G>T p.X676_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99536375; called by muse, varscan2
- ADAMTS15 | c.2393T>G p.F798C | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100143642; called by muse, mutect2, varscan2
- AFF2 | c.2002A>G p.R668G | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV99665478; called by muse, mutect2, varscan2
- APBB1 | c.1641C>G p.Y547* | Nonsense Mutation (SNP) | VAF 70/178 reads (39%) | catalogued as COSV100194223; called by muse, mutect2, varscan2
- ATF7IP | c.3767G>T p.C1256F | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99661959; called by muse, mutect2, varscan2
- BCAN | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228329; called by muse, mutect2, varscan2
- CACNA1C | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 54/87 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100220871; called by muse, mutect2, varscan2
- CD244 | c.1047A>C p.Q349H (on ENST00000368033 / NM_001166663.2; = p.Q344H on NM_016382.4) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs146201991, COSV99627135; called by muse, mutect2, varscan2
- CDKN1A | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55187626, COSV99781593; called by muse, mutect2, varscan2
- CEMIP | c.3430G>T p.A1144S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99587063; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99267457; called by muse, mutect2, varscan2
- CFAP61 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 108/188 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs142308308, COSV99844414; called by muse, mutect2, varscan2
- CLYBL | c.498A>C p.L166F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.682); catalogued as COSV100185522; called by muse, mutect2, varscan2
- CYSLTR2 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs1566110787, COSV99935322; called by muse, mutect2, varscan2
- DNAJB4 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV100883473; called by muse, mutect2, varscan2
- DUOX1 | c.2669G>C p.C890S | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV100368266; called by muse, mutect2, varscan2
- FAM83H | c.2906T>G p.L969R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100568037; called by muse, mutect2, varscan2
- FRA10AC1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100784737; called by muse, mutect2, varscan2
- GPR142 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.795); catalogued as COSV100170939; called by muse, mutect2, varscan2
- KIF13B | c.3847C>G p.Q1283E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs767563825, COSV101580766; called by muse, mutect2, varscan2
- KLHL32 | c.1014C>A p.H338Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.621); catalogued as COSV100987432; called by muse, mutect2, varscan2
- KRTAP13-4 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1449551043, COSV100481780; called by muse, mutect2, varscan2
- LAMA2 | c.1871T>C p.M624T | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101370707; called by muse, mutect2, varscan2
- LRRC19 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV101195817; called by muse, mutect2, varscan2
- LRRN2 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912920, COSV65783607; called by muse, mutect2, varscan2
- MAD2L1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.429); catalogued as COSV99633915; called by muse, mutect2, varscan2
- MAST1 | c.2324G>C p.R775P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV99263419; called by muse, mutect2, varscan2
- NCKAP1 | c.1196A>G p.D399G | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100720469; called by muse, mutect2, varscan2
- NCKAP5L | c.1542G>C p.E514D | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100259062; called by muse, mutect2, varscan2
- NCOR2 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100657713; called by muse, mutect2, varscan2
- NOS2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569806; called by muse, mutect2, varscan2
- NPEPPS | c.221T>A p.F74Y | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV100443882; called by muse, mutect2, varscan2
- NUTM1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV100412455; called by muse, mutect2, varscan2
- ORM1 | c.179A>T p.Q60L | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV52281130, COSV99407638; called by muse, mutect2, varscan2
- PCDHGA11 | c.2327A>G p.Y776C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.289); catalogued as rs1383467583, COSV99543208; called by muse, mutect2, varscan2
- PCLO | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as COSV100435434; called by muse, mutect2, varscan2
- PLK1 | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55621999; called by muse, mutect2, varscan2
- PRKCH | c.559C>G p.H187D | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV100273587; called by muse, mutect2, varscan2
- PTK2 | c.2690G>A p.S897N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV100570828; called by muse, mutect2, varscan2
- PTPN23 | c.3992A>T p.E1331V | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754079072, COSV99650853; called by muse, mutect2, varscan2
- RAC2 | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 119/301 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV99969587; called by muse, mutect2, varscan2
- RHBDF2 | c.925T>A p.S309T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV100489576; called by muse, mutect2, varscan2
- ROCK1 | c.362dup p.W122Lfs*25 | Frame Shift Ins (INS) | VAF 12/112 reads (11%) | catalogued as rs35810558; called by mutect2, pindel, varscan2
- RYR3 | c.10588G>T p.D3530Y (on ENST00000389232; = p.D3531Y on NM_001036.6) | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV101213469; called by muse, mutect2, varscan2
- SCN4A | c.4169T>C p.M1390T | Missense Mutation (SNP) | VAF 138/363 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV71126076; called by muse, mutect2, varscan2
- SLC30A1 | c.1109A>T p.H370L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1188914296, COSV100879146; called by muse, mutect2, varscan2
- SLC38A9 | c.734T>G p.L245R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.354); catalogued as COSV100591522; called by muse, mutect2, varscan2
- SLCO3A1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.227); catalogued as rs534712973, COSV100575749; called by muse, mutect2, varscan2
- SOS1 | c.3868C>T p.P1290S | Missense Mutation (SNP) | VAF 193/490 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as COSV101217133, COSV101217162; called by muse, mutect2, varscan2
- SPEF2 | c.4734G>T p.M1578I | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100289258, COSV57427909; called by muse, mutect2, varscan2
- TAF1 | c.2104A>G p.T702A (on ENST00000373790 / NM_138923.4; = p.T723A on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/95 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV99336509; called by muse, mutect2, varscan2
- TF | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99396204; called by mutect2, varscan2
- TRIML1 | c.773T>A p.L258* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100206208; called by muse, mutect2, varscan2
- USH2A | c.2612A>T p.K871I | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100239395; called by muse, mutect2, varscan2
- USP19 | c.1085G>A p.C362Y | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.186); catalogued as COSV100026388; called by muse, mutect2, varscan2
- WAPL | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100077107; called by muse, mutect2, varscan2
- WDFY3 | c.3512C>T p.S1171L | Missense Mutation (SNP) | VAF 76/105 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99884815; called by muse, mutect2, varscan2
- ADPRM | c.962del p.L321* | Frame Shift Del (DEL) | VAF 33/63 reads (52%) | called by mutect2, pindel, varscan2
- CAMSAP2 | c.3789dup p.Q1264Tfs*12 (on ENST00000236925 / NM_001297707.2; = p.Q1253Tfs*12 on NM_203459.3) | Frame Shift Ins (INS) | VAF 55/149 reads (37%) | called by mutect2, varscan2
- CSNK2A1 | c.12_17del p.V5_P6del | In Frame Del (DEL) | VAF 44/165 reads (27%) | called by mutect2, pindel, varscan2
- MRC1 | c.404T>A p.L135* | Nonsense Mutation (SNP) | VAF 174/428 reads (41%) | called by muse, mutect2
- MUSK | c.1899del p.F633Lfs*7 | Frame Shift Del (DEL) | VAF 47/133 reads (35%) | called by mutect2, pindel, varscan2
- TF | c.970dup p.V324Gfs*14 | Frame Shift Ins (INS) | VAF 45/126 reads (36%) | called by mutect2, varscan2
- ZNF638 | c.1728dup p.A577Sfs*16 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | called by mutect2, varscan2
- AGBL2 | c.1110G>A p.G370= | Silent (SNP) | VAF 89/200 reads (45%) | catalogued as COSV100101957; called by muse, mutect2, varscan2
- C9orf85 | c.288C>T p.C96= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs759417825, COSV58253981; called by muse, mutect2, varscan2
- CR1 | c.2523A>G p.Q841= | Silent (SNP) | VAF 197/473 reads (42%) | catalogued as COSV100887907; called by muse, mutect2, varscan2
- CSMD3 | c.2985T>C p.G995= (on ENST00000297405 / NM_001363185.1; = p.G891= on NM_052900.3) | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99842319; called by muse, mutect2, varscan2
- ENG | c.822T>A p.T274= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100785330; called by muse, mutect2, varscan2
- FAIM2 | c.363G>A p.V121= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as COSV100277652; called by muse, mutect2, varscan2
- G3BP2 | c.765T>G p.P255= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as COSV100692994; called by muse, mutect2, varscan2
- GPI | c.1249C>A p.R417= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV100731545; called by muse, mutect2, varscan2
- GPR75 | c.195G>A p.L65= | Silent (SNP) | VAF 90/214 reads (42%) | catalogued as COSV100766302; called by muse, mutect2, varscan2
- HIF3A | c.546G>A p.K182= (on ENST00000377670 / NM_152795.4; = p.K113= on NM_022462.4) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99355981; called by muse, mutect2, varscan2
- MEX3C | c.297G>T p.G99= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- MON1B | c.561G>T p.R187= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99941812; called by muse, mutect2, varscan2
- MRC1 | c.402T>A p.G134= | Silent (SNP) | VAF 170/424 reads (40%) | called by muse, mutect2
- SPEG | c.8574G>A p.A2858= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs1414519807, COSV100403278; called by muse, mutect2, varscan2
- TAS2R41 | c.252C>T p.F84= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV101281477, COSV101281508; called by muse, mutect2, varscan2
- WDR59 | c.1416A>G p.K472= | Silent (SNP) | VAF 84/180 reads (47%) | catalogued as COSV100049580; called by muse, mutect2, varscan2
- ACAD8 | c.-2C>T | 5'UTR (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55540747; called by muse, mutect2
- MFSD4B | c.*186del | 3'UTR (DEL) | VAF 16/138 reads (12%) | catalogued as rs540972233; called by mutect2, varscan2
- MTHFR | c.-13-315A>G | Intron (SNP) | VAF 40/135 reads (30%) | catalogued as rs1251919379, COSV100412099; called by muse, mutect2, varscan2
